Gene-level copy-number profile of tumor specimen AP-A5NG-87 from APOLLO case AP-A5NG, project APOLLO-LUAD (APOLLO1: Proteogenomic characterization of lung adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Solid carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IA; Tumor grade: G3.
Specimen AP-A5NG-87: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 6444ac4e-8ce7-41ff-990d-e09962d35853.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator AP-A5NG-FC (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,727 have no estimate.
https://portal.gdc.cancer.gov/files/3c642680-f22b-4d94-89cd-32d3de33768e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 531; copy number 1: 6,470; copy number 2: 34,377; copy number 3: 14,139; copy number 4: 3,037; copy number 5: 150; copy number 6: 56; copy number 7: 113; copy number 10: 23.

Homozygous deletions (total copy number 0; autosomes only): 19 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr18:45,034–73,545, 3 genes: AP001005.1, TUBB8B, AP001005.3.
- chr19:16,712,317–17,075,625, 12 genes: AC008737.2, NWD1, AC008737.3, SIN3B, AC008737.1, F2RL3, CPAMD8, RN7SL835P, RN7SL823P, AC020908.2, HAUS8, AC020908.1.
- chr19:39,196,964–39,237,293, 3 genes: NCCRP1, SYCN, IFNL3P1.
- chr21:12,999,676–13,016,692, 1 gene: AP001464.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 342 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:67,701,475–71,081,289, 47 genes, copy number 5: GNG12, RNU7-80P, GNG12-AS1, AL157407.1, DIRAS3, ARL5AP3, WLS, CTBP2P8, MIR1262, RPS7P4, COX6B1P7, ELOCP18, AL139413.1, RPE65, DEPDC1, AL138789.1, DEPDC1-AS1, TXNP2, LINC01707, LINC02791, LINC01758, LRRC7, SGO1P1, AL117353.1, RN7SL538P, PIN1P1, LRRC7-AS1, LRRC40, RN7SL242P, SRSF11, AL353771.1, ANKRD13C, HHLA3, HHLA3-AS1, CTH, Metazoa_SRP, AL354872.1, CHORDC1P5, CASP3P1, LINC01788, AL513285.1, PTGER3, AL031429.1, AL031429.2, ZRANB2-AS1, ZRANB2, MIR186.
- chr1:85,249,953–87,169,204, 35 genes, copy number 6: C1orf52, Y_RNA, BCL10, AL078459.1, DDAH1, Y_RNA, AL360219.1, AC092807.3, AC092807.2, CCN1, SNORD81, AC092807.1, ZNHIT6, COL24A1, RNA5SP51, AC104455.1, ODF2L, MIR7856, AC119749.1, CLCA2, CLCA1, CLCA4, CDCA4P2, CLCA4-AS1, CLCA3P, CLCA4-AS1, SH3GLB1, AL049597.1, SELENOF, HS2ST1, AL121989.1, AC093155.3, AC093155.2, AC093155.1, LINC01140.
- chr1:103,525,691–104,226,678, 12 genes, copy number 5: RNPC3, AMY2B, ACTG1P4, AMY2A, AMY1A, AC105272.1, AMY1B, AMYP1, AMY1C, AL136455.1, AC092506.1, FTLP17.
- chr1:143,419,625–143,883,575, 23 genes, copy number 5: AC239859.5, RNA5SP533, AC239859.3, AC239859.4, NKAIN1P1, AC239859.2, LINC02799, AC239859.1, NBPF17P, PFN1P12, RNU1-114P, RNVU1-17, RNVU1-23, RNVU1-18, AC239800.2, AC239800.1, FAM91A3P, AC239800.3, LINC02591, RNU1-143P, AC239798.1, AC239798.2, FCGR1CP.
- chr6:37,005,646–37,175,428, 4 genes, copy number 5: FGD2, COX6A1P2, RPL12P2, PIM1.
- chr7:16,916,359–17,346,152, 1 gene, copy number 5 (within-gene range 3–5): AHR.
- chr7:16,970,320–17,299,368, 1 gene, copy number 5 (within-gene range 3–5): AC073332.1.
- chr7:17,299,295–17,680,659, 5 genes, copy number 5: AC019117.3, SNORA63, AC019117.2, AC019117.1, AC006482.1.
- chr8:55,773,446–55,826,445, 1 gene, copy number 6: TGS1.
- chr8:127,072,694–128,564,679, 23 genes, copy number 10: CASC19, PRNCR1, AC020688.1, CASC8, AC018714.1, POU5F1B, CCAT2, AC104370.1, CASC11, MYC, PVT1, MIR1204, AC084123.1, TMEM75, MIR1205, RNVU1-32, MIR1206, AC103705.1, RNU4-25P, MIR1207, MIR1208, RN7SKP226, LINC00824.
- chr11:62,851,984–62,888,875, 9 genes, copy number 5: SNHG1, SNORD22, SNORD30, SNORD22, SNORD28, SNORD27, SNORD26, SNORD25, SLC3A2.
- chr11:65,487,241–65,498,405, 3 genes, copy number 7: LINC02736, AP000769.6, AP000769.2.
- chr20:56,688,401–62,776,996, 137 genes, copy number 5–7 (broad region; genes not listed).
- chr20:63,696,652–63,739,103, 5 genes, copy number 7 (within-gene range 3–7): TNFRSF6B, ARFRP1, ZGPAT, AL121845.3, AL121845.4.
- chr20:63,743,668–63,832,038, 1 gene, copy number 7 (within-gene range 4–7): ZBTB46.
- chr20:63,808,076–64,327,972, 35 genes, copy number 7: ZBTB46-AS1, C20orf181, AL118506.1, ABHD16B, TPD52L2, DNAJC5, RNU1-134P, MIR941-1, MIR941-2, MIR941-3, MIR941-4, MIR941-5, UCKL1, MIR1914, MIR647, UCKL1-AS1, ZNF512B, SAMD10, PRPF6, C20orf204, SOX18, TCEA2, AL355803.1, RGS19, MIR6813, OPRL1, LKAAEAR1, AL121581.3, MYT1, NPBWR2, PCMTD2, AL137028.2, CICP4, LINC00266-1, AL137028.1.

Autosomal genes at a single copy (total copy number 1): 5,249. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
